Somatic mutation profile of tumor specimen TCGA-AA-3693-01A (aliquot TCGA-AA-3693-01A-01W-0900-09) from TCGA case TCGA-AA-3693, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IV; Age at diagnosis: 77.9 years (28,459 days).
Specimen TCGA-AA-3693-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52efd546-3a60-4499-95a9-6c11064079c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3693-10A (Blood Derived Normal), aliquot TCGA-AA-3693-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f77cf50-0071-473c-814d-d783c673562f

The open-access MAF lists 163 somatic variants for this specimen: 117 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 43, Nonsense Mutation 7, Frame Shift Del 2, RNA 2, Splice Site 1, Intron 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PREX2 | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 22/53 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV55750189, COSV55751655, COSV99910567; called by muse, mutect2, varscan2
- A2M | c.3527A>T p.K1176M | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59392750; called by muse, mutect2, varscan2
- ABHD17B | c.563T>A p.V188D | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61009242; called by muse, mutect2, varscan2
- ABL2 | c.2095G>A p.D699N (on ENST00000502732 / NM_007314.4; = p.D684N on NM_005158.5) | Missense Mutation (SNP) | VAF 76/144 reads (53%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.085); catalogued as COSV61020661; called by muse, mutect2, varscan2
- ALG13 | c.2050A>T p.R684W | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99323121; called by muse, mutect2, varscan2
- ARFGEF3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs368160702; called by muse, mutect2, varscan2
- ARHGEF28 | c.2965C>T p.R989C | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747665438, COSV55248734; called by muse, mutect2, varscan2
- ASB18 | c.1247C>A p.A416D | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV58235974; called by muse, mutect2, varscan2
- ASXL3 | c.4631C>A p.A1544E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV52480184; called by muse, mutect2, varscan2
- ATPSCKMT | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV99725997; called by muse, mutect2
- BORA | c.1382G>A p.R461Q (on ENST00000613797; = p.R386Q on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 242/455 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as rs200969838, COSV64695942; called by muse, mutect2, varscan2
- C10orf120 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 72/176 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.066); catalogued as COSV61491661, COSV61492695; called by muse, mutect2, varscan2
- CACNA1E | c.6155G>A p.R2052Q (on ENST00000367573 / NM_001205293.3; = p.R2009Q on NM_000721.4) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs192353760, COSV62426406; called by muse, mutect2, varscan2
- CALD1 | c.1535G>A p.R512H (on ENST00000361675 / NM_033138.4; = p.R257H on NM_004342.7) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV62654464; called by muse, mutect2, varscan2
- CCDC120 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV64481800; called by muse, mutect2, varscan2
- CD163 | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 160/403 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.942); catalogued as COSV100776162; called by muse, mutect2, varscan2
- CD163 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 161/404 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100776163; called by muse, mutect2, varscan2
- CDK12 | c.3991C>T p.R1331* (on ENST00000447079 / NM_016507.4; = p.R1322* on NM_015083.3) | Nonsense Mutation (SNP) | VAF 49/110 reads (45%) | catalogued as COSV71003017; called by muse, mutect2, varscan2
- CDKN1B | c.410del p.P137Rfs*8 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | catalogued as rs1328655695, COSV99964122; called by mutect2, varscan2
- CFH | c.3446G>A p.R1149Q | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1064795727, COSV66413886; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD9 | c.3865C>A p.Q1289K | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54616624; called by muse, mutect2, varscan2
- COQ2 | c.682A>C p.N228H | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61022309; called by muse, mutect2, varscan2
- CREB5 | c.407C>T p.P136L (on ENST00000357727 / NM_182898.4; = p.P129L on NM_004904.3) | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs555693522, COSV63217153, COSV63228338; called by muse, mutect2, varscan2
- CSNK2A2 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52644189; called by muse, mutect2, varscan2
- CTPS2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 132/358 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV63724450; called by muse, mutect2, varscan2
- DACH2 | c.890C>A p.P297Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV64169404, COSV64186758; called by muse, varscan2
- DIRAS2 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65370810; called by muse, mutect2, varscan2
- DMP1 | c.292G>T p.G98* | Nonsense Mutation (SNP) | VAF 45/196 reads (23%) | catalogued as COSV56819746, COSV56820428; called by muse, mutect2, varscan2
- DYNC1I1 | c.856A>T p.K286* | Nonsense Mutation (SNP) | VAF 133/592 reads (22%) | catalogued as COSV61471963; called by muse, mutect2, varscan2
- ESYT3 | c.2654G>C p.R885T | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV67442185; called by muse, mutect2, varscan2
- EVA1A | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 240/250 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52062676; called by muse, mutect2, varscan2
- FREM2 | c.3328C>A p.P1110T | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99751199; called by muse, mutect2
- FRMPD3 | c.323C>A p.P108Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760069538, COSV52197497; called by muse, mutect2, varscan2
- GRID1 | c.1822G>A p.A608T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs536754961, COSV60030856; called by muse, mutect2, varscan2
- HEATR6 | c.3211C>A p.Q1071K | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as COSV51749247; called by muse, mutect2
- HECW1 | c.352+1G>T p.X118_splice | Splice Site (SNP) | VAF 26/126 reads (21%) | catalogued as COSV101224367; called by muse, mutect2, varscan2
- HECW1 | c.4504C>T p.R1502W | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1197568130, COSV101224368; called by muse, mutect2, varscan2
- HNF4A | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as COSV100291758; called by muse, mutect2
- IDH2 | c.950C>G p.S317* | Nonsense Mutation (SNP) | VAF 27/33 reads (82%) | catalogued as COSV51565842; called by muse, mutect2, varscan2
- ILDR1 | c.1217C>G p.S406C (on ENST00000344209 / NM_001199799.2; = p.S362C on NM_175924.4) | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.436); catalogued as COSV56554066; called by muse, mutect2, varscan2
- IRF4 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705482; called by muse, mutect2
- KIT | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 39/63 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV55423126; called by muse, mutect2, varscan2
- LAMA1 | c.8920G>A p.D2974N | Missense Mutation (SNP) | VAF 23/30 reads (77%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV67544775; called by muse, mutect2, varscan2
- LMX1B | c.469G>A p.V157M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs767072869, COSV62742039; called by muse, mutect2, varscan2
- LRRIQ3 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs770907166, COSV63050390; called by muse, mutect2, varscan2
- MAGEC1 | c.3301T>A p.S1101T | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV53582009; called by muse, mutect2, varscan2
- MAGI2 | c.2958G>T p.M986I | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); catalogued as rs779365635, COSV62700627; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP10 | c.1496C>G p.S499C | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.112); catalogued as COSV69362690, COSV69365049; called by muse, mutect2, varscan2
- MAP3K12 | c.1780C>G p.L594V | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV57232714, COSV57236544; called by muse, mutect2, varscan2
- MAPT | c.1165G>C p.E389Q (on ENST00000262410 / NM_001377265.1; = p.E314Q on NM_016835.4) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1463829855, COSV52247985, COSV52248769; called by muse, mutect2, varscan2
- MATN4 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 26/38 reads (68%) | PolyPhen probably damaging (0.999); catalogued as rs759206402, COSV59215825; called by muse, mutect2, varscan2
- MCEE | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 48/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54907267; called by muse, mutect2, varscan2
- MYOF | c.2882C>T p.A961V | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV63710961; called by muse, mutect2, varscan2
- NAALAD2 | c.747A>T p.L249F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.957); catalogued as COSV58966437; called by muse, mutect2, varscan2
- NBEA | c.1909G>A p.V637I | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100084661; called by muse, mutect2
- NEXMIF | c.2677G>T p.A893S | Missense Mutation (SNP) | VAF 159/319 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV50062867, COSV50126092; called by muse, mutect2, varscan2
- NPR2 | c.2644G>A p.V882I | Missense Mutation (SNP) | VAF 62/153 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs55700371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR2J2 | c.553C>T p.L185F | Missense Mutation (SNP) | VAF 24/399 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.959); catalogued as COSV65847765; called by muse, mutect2
- OR2M4 | c.574A>G p.T192A | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292742428, COSV100141540; called by muse, mutect2
- OR5AN1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 146/348 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs149354660; called by muse, mutect2, varscan2
- OSBPL7 | c.2129A>G p.Y710C | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV50116002; called by muse, mutect2, varscan2
- PAPPA | c.2054C>T p.T685I | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60292291; called by muse, mutect2, varscan2
- PCDHGB6 | c.437C>A p.A146E | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.213); catalogued as COSV54038126; called by muse, mutect2
- PCOLCE2 | c.446G>T p.R149I | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs1206179508, COSV55998999, COSV56002132, COSV56002313; called by muse, mutect2, varscan2
- PLK4 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 79/340 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54639524; called by muse, mutect2, varscan2
- PLPPR4 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV64566884, COSV64567801; called by muse, mutect2, varscan2
- PNLDC1 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs893027492, COSV51708221; called by muse, mutect2, varscan2
- POLR2H | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55604492; called by muse, mutect2, varscan2
- POP1 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 8/194 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as COSV100856137; called by muse, mutect2
- PPP6R1 | c.1862A>G p.D621G | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV69800854; called by muse, mutect2, varscan2
- PRELP | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58117639; called by muse, mutect2, varscan2
- PROM2 | c.1496G>T p.G499V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58300978; called by muse, mutect2, varscan2
- PTGFR | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.454); catalogued as rs751233611, COSV66114802, COSV66116853; called by muse, mutect2, varscan2
- RAD21 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99815669; called by muse, mutect2
- RBMS3 | c.425T>A p.L142Q | Missense Mutation (SNP) | VAF 117/367 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56169885; called by muse, mutect2, varscan2
- RNF17 | c.4590C>G p.C1530W | Missense Mutation (SNP) | VAF 110/262 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55052243; called by muse, mutect2, varscan2
- RNF180 | c.832T>A p.Y278N | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56961199, COSV56965407; called by muse, mutect2, varscan2
- RNF6 | c.910C>T p.R304* | Nonsense Mutation (SNP) | VAF 49/640 reads (8%) | catalogued as COSV60418090; called by muse, mutect2
- SATB1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV58672960; called by muse, mutect2, varscan2
- SEMA3A | c.1672A>T p.I558L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV54888803; called by muse, mutect2
- SFMBT2 | c.211C>A p.Q71K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV62817076; called by muse, mutect2, varscan2
- SLC30A10 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1558249270, COSV63076010; called by muse, mutect2, varscan2
- SNX7 | c.339C>A p.F113L | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV60272279; called by muse, mutect2, varscan2
- SOHLH2 | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65904157; called by muse, mutect2, varscan2
- SPRY3 | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 13/402 reads (3%) | catalogued as COSV100249588; called by muse, mutect2
- ST8SIA4 | c.470G>C p.G157A | Missense Mutation (SNP) | VAF 38/91 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV51516814; called by muse, mutect2, varscan2
- STAG3 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1434389254, COSV57935259; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV59138613; called by muse, mutect2, varscan2
- SYNE1 | c.13360G>A p.E4454K (on ENST00000367255 / NM_182961.4; = p.E4383K on NM_033071.3) | Missense Mutation (SNP) | VAF 53/105 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs192299401, COSV55109748; called by muse, mutect2, varscan2
- SYNE4 | c.1184T>C p.L395P | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61011080; called by muse, mutect2, varscan2
- SYNGAP1 | c.3529G>A p.E1177K | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV53386858; called by muse, mutect2
- SYT15 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs371278933, COSV65431285; called by mutect2, varscan2
- SYTL5 | c.1844A>G p.Y615C | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52905884; called by muse, mutect2, varscan2
- TAF9B | c.176G>C p.S59T | Missense Mutation (SNP) | VAF 113/260 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1557250263, COSV100540772; called by muse, mutect2, varscan2
- TAF9B | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100540773; called by muse, mutect2, varscan2
- THAP12 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV52613241; called by muse, mutect2, varscan2
- TIAM1 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs781362985, COSV54575725; called by muse, mutect2, varscan2
- TMTC2 | c.1246G>C p.G416R | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58284667; called by muse, mutect2, varscan2
- TNFSF18 | c.217T>A p.L73I | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV53441918; called by muse, mutect2, varscan2
- TP53 | c.370T>G p.C124G | Missense Mutation (SNP) | VAF 81/97 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs730881997, COSV52680549, COSV52752618; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM9 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 36/45 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.508); catalogued as rs1260763850, COSV53625137; called by muse, mutect2, varscan2
- TTN | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 21/60 reads (35%) | PolyPhen possibly damaging (0.855); catalogued as rs766680186, COSV60033306; called by muse, mutect2, varscan2
- UBAP2L | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.76); PolyPhen benign (0.18); catalogued as COSV55181669; called by muse, mutect2, varscan2
- UGT8 | c.1315C>T p.H439Y | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs767674399, COSV60421328; called by muse, mutect2, varscan2
- USP28 | c.930T>G p.N310K | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.065); catalogued as COSV50193388; called by muse, mutect2, varscan2
- WNK3 | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV63616040; called by muse, mutect2, varscan2
- XRRA1 | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs369302102, COSV58496163; called by muse, mutect2, varscan2
- ZNF100 | c.673A>G p.R225G | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs766952300, COSV59750179; called by muse, mutect2, varscan2
- ZNF335 | c.2306G>T p.C769F | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV59820418; called by muse, mutect2, varscan2
- ZNF335 | c.204G>A p.E68= | Splice Region (SNP) | VAF 23/38 reads (61%) | catalogued as COSV59820424; called by muse, mutect2, varscan2
- ZNF341 | c.1625G>T p.C542F (on ENST00000375200 / NM_001282935.1; = p.C535F on NM_032819.4) | Missense Mutation (SNP) | VAF 63/398 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV61011344; called by muse, mutect2, varscan2
- ZNF420 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58496532; called by muse, mutect2, varscan2
- ZNF462 | c.7513A>T p.K2505* | Nonsense Mutation (SNP) | VAF 42/97 reads (43%) | catalogued as COSV52951453; called by muse, mutect2, varscan2
- ZNF780A | c.1445T>G p.F482C | Missense Mutation (SNP) | VAF 149/398 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61816812; called by muse, mutect2, varscan2
- ZNF875 | c.1862A>C p.H621P | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.831); catalogued as COSV60994072; called by muse, mutect2, varscan2
- APC | c.3885del p.A1296Qfs*9 | Frame Shift Del (DEL) | VAF 110/164 reads (67%) | called by mutect2, pindel, varscan2
- SPECC1 | c.1703_1714del p.A568_V571del | In Frame Del (DEL) | VAF 11/84 reads (13%) | called by mutect2, pindel
- ACSL4 | c.1035G>A p.P345= (on ENST00000340800 / NM_022977.2; = p.P304= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/208 reads (4%) | catalogued as rs1409803653, COSV61614030; called by muse, mutect2
- ACVR1C | c.1404C>T p.N468= | Silent (SNP) | VAF 50/138 reads (36%) | catalogued as rs762191679, COSV54645642; called by muse, mutect2, varscan2
- AGFG1 | c.1317T>G p.A439= | Silent (SNP) | VAF 5/106 reads (5%) | catalogued as COSV100029214; called by muse, mutect2
- AKAP6 | c.168C>T p.P56= | Silent (SNP) | VAF 83/96 reads (86%) | catalogued as rs896675629, COSV55234277; called by muse, mutect2, varscan2
- AR | c.2307G>T p.L769= | Silent (SNP) | VAF 13/136 reads (10%) | catalogued as COSV65964374; called by muse, mutect2, varscan2
- ARL11 | c.198G>A p.G66= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs1169388505, COSV56292073, COSV56292229; called by muse, mutect2, varscan2
- ASB17 | c.129C>T p.Y43= | Silent (SNP) | VAF 90/211 reads (43%) | catalogued as rs199681630; called by muse, mutect2, varscan2
- ATRX | c.1110T>C p.Y370= | Silent (SNP) | VAF 128/312 reads (41%) | catalogued as rs371831155, COSV64883920; called by muse, mutect2, varscan2
- CASQ1 | c.487T>C p.L163= | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as COSV63624587; called by muse, mutect2, varscan2
- CD101 | c.1650G>A p.P550= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as rs754141259, COSV56717142, COSV56721357; called by muse, mutect2, varscan2
- CDH9 | c.1290T>A p.I430= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1411708188, COSV99158176; called by muse, mutect2
- CEACAM20 | c.1233C>T p.D411= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as rs559550466, COSV57603381; called by muse, mutect2, varscan2
- COL5A3 | c.4872C>T p.D1624= | Silent (SNP) | VAF 62/93 reads (67%) | catalogued as rs201892356, COSV53419672; called by muse, mutect2, varscan2
- EBF3 | c.669C>A p.G223= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV62482118; called by muse, mutect2, varscan2
- EFEMP1 | c.171T>A p.G57= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV62618001, COSV62618104; called by muse, mutect2, varscan2
- EFR3A | c.2025T>C p.S675= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV54462603; called by muse, mutect2, varscan2
- GRAMD2A | c.993G>A p.A331= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as rs771204174, COSV59033381; called by muse, mutect2, varscan2
- HCFC1 | c.402G>A p.P134= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV60078053; called by muse, mutect2, varscan2
- HMCN1 | c.6294C>T p.L2098= | Silent (SNP) | VAF 7/162 reads (4%) | catalogued as COSV99636473; called by muse, mutect2
- IGF2R | c.3162G>T p.L1054= | Silent (SNP) | VAF 16/215 reads (7%) | catalogued as rs1297352420, COSV100808257; called by muse, mutect2
- KLRB1 | c.411A>G p.E137= | Silent (SNP) | VAF 121/250 reads (48%) | catalogued as COSV57590458; called by muse, mutect2, varscan2
- LIMD1 | c.546C>T p.N182= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV56270545; called by muse, mutect2, varscan2
- MCEE | c.207G>T p.L69= | Silent (SNP) | VAF 49/194 reads (25%) | catalogued as COSV54907244; called by muse, mutect2, varscan2
- NCAPD2 | c.3900C>T p.I1300= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV57522106; called by muse, mutect2, varscan2
- OR5V1 | c.315T>A p.V105= | Silent (SNP) | VAF 19/361 reads (5%) | catalogued as COSV101011487; called by muse, mutect2
- PCDHGA3 | c.2070T>A p.T690= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99547873; called by muse, mutect2, varscan2
- PCDHGA6 | c.2094C>T p.A698= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99541363; called by mutect2, varscan2
- PDILT | c.1632C>T p.Y544= | Silent (SNP) | VAF 156/341 reads (46%) | catalogued as rs374255958, COSV56701088; called by muse, mutect2
- PNO1 | c.333G>A p.L111= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV99718519; called by muse, mutect2
- RAB33B | c.621T>C p.L207= | Silent (SNP) | VAF 53/284 reads (19%) | catalogued as COSV59778195; called by muse, mutect2, varscan2
- RAB36 | c.72G>A p.T24= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1262744997, COSV53272362; called by muse, mutect2
- RBM12B | c.276A>G p.G92= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as COSV101197166; called by muse, mutect2
- SCN11A | c.882G>A p.P294= | Silent (SNP) | VAF 600/978 reads (61%) | catalogued as rs761791422, COSV56568277, COSV56569488; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC26A6 | c.1446G>T p.T482= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56575796; called by muse, mutect2, varscan2
- SPTBN2 | c.5583C>T p.D1861= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs557448224, COSV59461628; called by muse, mutect2, varscan2
- SUPT20HL2 | c.1071G>A p.S357= | Silent (SNP) | VAF 75/150 reads (50%) | catalogued as rs1209226055; called by muse, mutect2, varscan2
- SYT5 | c.738C>T p.S246= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs141734238, COSV62829772; called by muse, mutect2, varscan2
- TAP1 | c.2058T>C p.S686= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs1433372280, COSV62755836; called by muse, mutect2, varscan2
- TAS2R30 | c.486G>A p.V162= | Silent (SNP) | VAF 134/414 reads (32%) | catalogued as COSV67862828; called by muse, varscan2
- TMEM231 | c.672C>G p.T224= (on ENST00000258173 / NM_001077418.3; = p.T253= on NM_001077416.2) | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV50740089, COSV99260129; called by muse, mutect2, varscan2
- TRGV2 | c.267C>T p.Y89= | Silent (SNP) | VAF 102/398 reads (26%) | catalogued as rs759662908; called by muse, mutect2, varscan2
- WDR36 | c.262C>A p.R88= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as COSV72411506; called by muse, mutect2, varscan2
- ZFHX4 | c.336C>T p.N112= | Silent (SNP) | VAF 98/211 reads (46%) | catalogued as COSV51489898; called by muse, mutect2, varscan2
- BMP1 | c.731-200C>T | Intron (SNP) | VAF 7/180 reads (4%) | catalogued as rs1563245274, COSV100110184; called by muse, mutect2
- FAM183BP | n.1265C>A | RNA (SNP) | VAF 42/376 reads (11%) | called by muse, mutect2, varscan2
- MIRLET7A1 | n.12A>G | RNA (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
